Somatic mutation profile of tumor specimen C3L-04072-01 (aliquot CPT0221240007) from CPTAC case C3L-04072, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G3; Age at diagnosis: 55.9 years (20,413 days).
Specimen C3L-04072-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a320618f-ec1f-4b62-9b42-66843c03b89c.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3L-04072-31 (Blood Derived Normal), aliquot CPT0220470002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/63d2e3e4-e75e-480d-99e3-d9d71f191361

The open-access MAF lists 78 somatic variants for this specimen: 46 protein-altering or splice-affecting, 12 silent, 20 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 36, 5'Flank 16, Silent 12, Nonsense Mutation 4, Frame Shift Ins 3, Frame Shift Del 1, 3'UTR 1, 5'UTR 1, RNA 1, Splice Site 1, Splice Region 1, Intron 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- KRAS | c.35G>A p.G12D | Missense Mutation (SNP) | VAF 375/831 reads (45%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen benign (0.303); catalogued as rs121913529, COSV55497369, COSV55497419, COSV55497479; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- MYH7 | c.2080C>T p.R694C | Missense Mutation (SNP) | VAF 49/516 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.963); catalogued as rs727504240, CM992647; ClinVar: uncertain significance / likely pathogenic; called by muse, mutect2
- BNIP3L | c.76C>G p.L26V | Missense Mutation (SNP) | VAF 76/510 reads (15%) | SIFT tolerated, low confidence (0.2); PolyPhen possibly damaging (0.874); catalogued as rs950774191; called by muse, varscan2
- CAMSAP1 | c.2401C>G p.Q801E | Missense Mutation (SNP) | VAF 85/366 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.986); catalogued as rs749774202, COSV56719156, COSV56721419; called by muse, mutect2, varscan2
- CASP8AP2 | c.5510G>A p.R1837K | Missense Mutation (SNP) | VAF 80/376 reads (21%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99387013; called by muse, varscan2
- GALT | c.237C>G p.I79M | Missense Mutation (SNP) | VAF 32/400 reads (8%) | SIFT deleterious (0.05); PolyPhen benign (0.003); catalogued as COSV66593154; called by muse, mutect2
- ITGA1 | c.169G>A p.E57K | Missense Mutation (SNP) | VAF 39/159 reads (25%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.468); catalogued as rs567216405; called by muse, mutect2, varscan2
- KLRK1 | c.388C>T p.Q130* | Nonsense Mutation (SNP) | VAF 30/562 reads (5%) | catalogued as COSV53698207, COSV99555187; called by muse, mutect2
- NEUROD1 | c.577C>T p.R193W | Missense Mutation (SNP) | VAF 13/240 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV54551146; called by muse, mutect2
- PAK6 | c.-118G>A | Splice Region (SNP) | VAF 47/243 reads (19%) | catalogued as rs566666956; called by muse, mutect2, varscan2
- PDE8A | c.1243C>G p.L415V | Missense Mutation (SNP) | VAF 71/361 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs751681396; called by muse, mutect2, varscan2
- PLCG2 | c.835G>A p.E279K | Missense Mutation (SNP) | VAF 14/352 reads (4%) | SIFT tolerated (0.28); PolyPhen probably damaging (0.996); catalogued as COSV100842170; called by muse, mutect2
- POLR2E | c.25C>G p.R9G | Missense Mutation (SNP) | VAF 80/393 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.91); catalogued as COSV53124052; called by muse, mutect2, varscan2
- RAD52 | c.229G>A p.E77K | Missense Mutation (SNP) | VAF 81/494 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99942510; called by muse, mutect2, varscan2
- RPAP1 | c.1762C>T p.R588W | Missense Mutation (SNP) | VAF 35/188 reads (19%) | SIFT deleterious (0.01); PolyPhen benign (0.066); catalogued as rs1206677867, COSV58538487; called by muse, mutect2, varscan2
- TNIK | c.1897G>A p.V633M | Missense Mutation (SNP) | VAF 81/321 reads (25%) | SIFT tolerated (0.24); PolyPhen possibly damaging (0.644); catalogued as rs780229852; called by muse, mutect2, varscan2
- TP53 | c.672G>C p.E224D | Missense Mutation (SNP) | VAF 133/507 reads (26%) | SIFT tolerated (0.06); PolyPhen benign (0.023); catalogued as CS100446, COSV52678333, COSV52681634, COSV52721244; called by muse, mutect2, varscan2
- TRIP12 | c.3011G>A p.R1004Q | Missense Mutation (SNP) | VAF 80/595 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.921); catalogued as rs1366848506; called by muse, mutect2, varscan2
- TUFM | c.193A>G p.T65A | Missense Mutation (SNP) | VAF 242/1127 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.992); catalogued as rs1364606244; called by muse, mutect2, varscan2
- VPS13C | c.4546G>C p.D1516H (on ENST00000644861 / NM_020821.3; = p.D1473H on NM_017684.5) | Missense Mutation (SNP) | VAF 20/492 reads (4%) | SIFT deleterious (0.01); PolyPhen benign (0.352); catalogued as COSV99827918; called by muse, mutect2
- ZNF343 | c.1211C>G p.S404* | Nonsense Mutation (SNP) | VAF 108/321 reads (34%) | catalogued as rs773320253; called by muse, mutect2, varscan2
- ACSL5 | c.443C>T p.S148F (on ENST00000354273; = p.S204F on NM_016234.3) | Missense Mutation (SNP) | VAF 26/161 reads (16%) | SIFT tolerated (0.13); PolyPhen benign (0.05); called by muse, mutect2, varscan2
- CASP8AP2 | c.5453C>T p.S1818L | Missense Mutation (SNP) | VAF 76/321 reads (24%) | SIFT tolerated (0.37); PolyPhen benign (0.001); called by muse, varscan2
- CENPB | c.82A>T p.K28* | Nonsense Mutation (SNP) | VAF 155/468 reads (33%) | called by muse, mutect2, varscan2
- CLCN1 | c.715G>A p.A239T | Missense Mutation (SNP) | VAF 95/483 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- CYSLTR1 | c.997G>T p.E333* | Nonsense Mutation (SNP) | VAF 10/40 reads (25%) | called by muse, mutect2, varscan2
- DDIAS | c.2795A>C p.K932T | Missense Mutation (SNP) | VAF 38/205 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- DNAI3 | c.1281C>G p.I427M | Missense Mutation (SNP) | VAF 10/212 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.979); called by muse, mutect2
- EIF3C | c.937G>A p.E313K | Missense Mutation (SNP) | VAF 30/668 reads (4%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.86); called by muse, mutect2
- HMGCR | c.2582A>G p.H861R | Missense Mutation (SNP) | VAF 111/514 reads (22%) | SIFT deleterious (0.01); PolyPhen benign (0.19); called by muse, varscan2
- HPSE2 | c.331G>A p.A111T | Missense Mutation (SNP) | VAF 155/658 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.323); called by muse, mutect2, varscan2
- HSD17B11 | c.92G>C p.R31T | Missense Mutation (SNP) | VAF 38/514 reads (7%) | SIFT deleterious (0); PolyPhen possibly damaging (0.873); called by muse, mutect2
- KCNJ8 | c.1126C>A p.H376N | Missense Mutation (SNP) | VAF 120/876 reads (14%) | SIFT tolerated (0.3); PolyPhen possibly damaging (0.53); called by muse, mutect2, varscan2
- KCNK1 | c.125C>T p.S42F | Missense Mutation (SNP) | VAF 58/1014 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- MAN1A1 | c.1607G>C p.R536T | Missense Mutation (SNP) | VAF 14/332 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- MKI67 | c.2860T>A p.W954R | Missense Mutation (SNP) | VAF 210/951 reads (22%) | SIFT tolerated (0.35); PolyPhen benign (0.007); called by muse, mutect2, varscan2
- MMP19 | c.1110dup p.K371Qfs*5 | Frame Shift Ins (INS) | VAF 117/564 reads (21%) | called by mutect2, pindel, varscan2
- MYEF2 | c.41G>C p.G14A | Missense Mutation (SNP) | VAF 95/457 reads (21%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.215); called by muse, mutect2, varscan2
- PDE4DIP | c.2722del p.E908Kfs*10 | Frame Shift Del (DEL) | VAF 101/488 reads (21%) | called by mutect2, pindel, varscan2
- PKHD1 | c.11729C>T p.S3910L | Missense Mutation (SNP) | VAF 40/612 reads (7%) | SIFT tolerated (0.1); PolyPhen benign (0.001); called by muse, mutect2
- PLXNC1 | c.3966+1G>T p.X1322_splice | Splice Site (SNP) | VAF 108/417 reads (26%) | called by muse, mutect2, varscan2
- RNF168 | c.449_450insA p.A151Gfs*25 | Frame Shift Ins (INS) | VAF 176/912 reads (19%) | called by mutect2, pindel*, varscan2*
- RNF43 | c.130dup p.Q44Pfs*31 | Frame Shift Ins (INS) | VAF 176/953 reads (18%) | called by mutect2, pindel, varscan2
- SMCO2 | c.718G>A p.E240K | Missense Mutation (SNP) | VAF 8/222 reads (4%) | SIFT tolerated (0.95); PolyPhen benign (0.067); called by muse, mutect2
- VPS41 | c.1019C>T p.S340F | Missense Mutation (SNP) | VAF 23/252 reads (9%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.571); called by muse, mutect2
- ZNF354A | c.431T>A p.I144K | Missense Mutation (SNP) | VAF 87/415 reads (21%) | SIFT tolerated (0.93); PolyPhen benign (0); called by muse, mutect2, varscan2
- AHNAK | c.5916G>A p.L1972= | Silent (SNP) | VAF 41/989 reads (4%) | catalogued as COSV57221415; called by muse, mutect2
- AHNAK2 | c.5268C>G p.L1756= | Silent (SNP) | VAF 76/1057 reads (7%) | called by muse, mutect2
- BEST1 | c.441C>G p.V147= | Silent (SNP) | VAF 20/426 reads (5%) | called by muse, mutect2
- DNAJC5B | c.273C>T p.A91= | Silent (SNP) | VAF 83/606 reads (14%) | catalogued as COSV99395479; called by muse, mutect2, varscan2
- HTR7 | c.384C>G p.L128= | Silent (SNP) | VAF 36/560 reads (6%) | called by muse, mutect2
- NLRC3 | c.339C>T p.R113= | Silent (SNP) | VAF 103/362 reads (28%) | catalogued as rs373142707; called by muse, mutect2, varscan2
- OR52E8 | c.468G>C p.L156= | Silent (SNP) | VAF 71/187 reads (38%) | called by muse, mutect2, varscan2
- RRP8 | c.1272C>T p.F424= | Silent (SNP) | VAF 12/60 reads (20%) | catalogued as rs144962503; called by muse, mutect2, varscan2
- RWDD2B | c.498C>T p.V166= | Silent (SNP) | VAF 24/408 reads (6%) | called by muse, mutect2
- TOP1 | c.1704C>T p.L568= | Silent (SNP) | VAF 18/264 reads (7%) | catalogued as COSV63694814; called by muse, mutect2
- TPO | c.1506G>A p.R502= | Silent (SNP) | VAF 128/546 reads (23%) | catalogued as rs773237793; called by muse, mutect2, varscan2
- ZBTB37 | c.51T>A p.S17= | Silent (SNP) | VAF 65/246 reads (26%) | called by muse, mutect2, varscan2
- AC002511.3 | n.325-111C>T | Intron (SNP) | VAF 27/108 reads (25%) | catalogued as rs145775447; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65501795 G>A | 5'Flank (SNP) | VAF 43/281 reads (15%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502603 G>A | 5'Flank (SNP) | VAF 14/81 reads (17%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65502918 G>A | 5'Flank (SNP) | VAF 41/219 reads (19%) | called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503064 G>A | 5'Flank (SNP) | VAF 24/148 reads (16%) | catalogued as rs755452277; called by muse, mutect2, varscan2
- AP000769.3 | chr11:65503835 G>A | 5'Flank (SNP) | VAF 28/135 reads (21%) | called by muse, varscan2
- AP000769.3 | chr11:65505304 G>A | 5'Flank (SNP) | VAF 53/300 reads (18%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65498368 G>C | 5'Flank (SNP) | VAF 38/219 reads (17%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499079 G>A | 5'Flank (SNP) | VAF 44/267 reads (16%) | catalogued as rs773811321; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499309 G>A | 5'Flank (SNP) | VAF 63/374 reads (17%) | called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499509 G>A | 5'Flank (SNP) | VAF 46/265 reads (17%) | called by muse, varscan2
- AP000769.5 | chr11:65499606 G>A | 5'Flank (SNP) | VAF 42/266 reads (16%) | called by muse, varscan2
- AP000769.5 | chr11:65499691 G>A | 5'Flank (SNP) | VAF 33/191 reads (17%) | catalogued as rs187715624; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65499943 G>A | 5'Flank (SNP) | VAF 30/184 reads (16%) | catalogued as rs899566078; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500073 G>C | 5'Flank (SNP) | VAF 41/298 reads (14%) | catalogued as rs1565676467; called by muse, mutect2, varscan2
- AP000769.5 | chr11:65500950 G>C | 5'Flank (SNP) | VAF 55/307 reads (18%) | called by muse, mutect2, varscan2
- PEX7 | c.-17C>T | 5'UTR (SNP) | VAF 91/801 reads (11%) | catalogued as rs1562723762; called by muse, mutect2, varscan2
- PLEK | c.*2G>A | 3'UTR (SNP) | VAF 24/296 reads (8%) | called by muse, mutect2
- PTPN20CP | n.198G>A | RNA (SNP) | VAF 169/814 reads (21%) | called by muse, mutect2, varscan2
- ZNF774 | chr15:90349149 C>T | 5'Flank (SNP) | VAF 104/518 reads (20%) | called by muse, mutect2, varscan2
